Somatic mutation profile of tumor specimen MMRF_2651_1_BM_CD138pos (aliquot MMRF_2651_1_BM_CD138pos_T1_KHS5U_L13770) from MMRF case MMRF_2651, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,425 days).
Specimen MMRF_2651_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61aa4bba-87c3-431b-95ef-71aa66a42006.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2651_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2651_1_PB_WBC_C3_KHS5U_L13771; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178fe0d9-141c-4541-9c13-bd18b9aedf9f

The open-access MAF lists 236 somatic variants for this specimen: 97 protein-altering or splice-affecting, 28 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, 3'UTR 49, Intron 33, Silent 28, 5'UTR 11, 5'Flank 11, Nonsense Mutation 10, RNA 4, 3'Flank 3, Splice Region 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK1 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 14/129 reads (11%) | catalogued as rs752081377; called by muse, mutect2
- ANKEF1 | c.2202G>C p.E734D | Missense Mutation (SNP) | VAF 121/277 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777080365, COSV65692271, COSV65693018; called by muse, mutect2, varscan2
- CASKIN1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340471555; called by muse, mutect2
- CDH2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52296787; called by muse, mutect2, varscan2
- CFD | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1304103523; called by muse, mutect2, varscan2
- COL18A1 | c.2083G>A p.V695I (on ENST00000359759 / NM_130444.3; = p.V460I on NM_030582.4) | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as rs775334835, COSV62700621; called by muse, mutect2, varscan2
- EPB41L3 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59454713; called by muse, mutect2, varscan2
- EPX | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as COSV56594937; called by muse, mutect2, varscan2
- GPRIN3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60885313; called by muse, mutect2
- IDI2 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1399672727; called by muse, mutect2
- IFT140 | c.2195G>A p.R732K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68486891; called by muse, mutect2, varscan2
- IGKV4-1 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs753725831; called by muse, varscan2
- IGKV5-2 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 109/115 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs536534315; called by muse, varscan2
- KLHL40 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763283033, CM149959, COSV55137070; called by muse, mutect2, varscan2
- KRT24 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs200625015, COSV52879845; called by muse, mutect2, varscan2
- MAGEA10 | c.231T>G p.D77E | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV54884142; called by muse, mutect2, varscan2
- MEGF11 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140370405; called by muse, mutect2
- MEPCE | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as rs1427984754; called by muse, mutect2, varscan2
- MYBPHL | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 46/77 reads (60%) | catalogued as rs191294010; called by muse, mutect2, varscan2
- NDUFS1 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1254004851; called by muse, mutect2
- PCLO | c.9925G>T p.E3309* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | catalogued as COSV61617745; called by muse, mutect2
- POLE | c.2320-2A>C p.X774_splice | Splice Site (SNP) | VAF 50/112 reads (45%) | catalogued as COSV57673820; called by muse, mutect2, varscan2
- PPP6R2 | c.2601-8C>A | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as rs775319051; called by muse, varscan2
- PTPRS | c.4741G>C p.D1581H | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53625575; called by muse, mutect2, varscan2
- TOP3A | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as rs1360563127; called by muse, mutect2, varscan2
- TTC7A | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs747695657, COSV55414209; called by muse, mutect2, varscan2
- UCN2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371104367; called by muse, mutect2, varscan2
- ZSWIM8 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101289881; called by muse, mutect2, varscan2
- AC006059.2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- ACTR6 | c.119_124del p.F40_A42delinsS | In Frame Del (DEL) | VAF 31/218 reads (14%) | called by mutect2, pindel, varscan2
- AFF3 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1L2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ANKS1B | c.3742T>C p.F1248L (on ENST00000547776 / NM_152788.4; = p.F414L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/269 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); called by muse, mutect2
- ARMC4 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AZIN2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BIRC6 | c.14568G>T p.Q4856H | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.473); called by muse, mutect2
- BOD1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CACNA1H | c.6425G>A p.G2142D | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2
- CCDC88C | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- CFAP92 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLEC19A | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DDX3X | c.1133T>C p.M378T (on ENST00000399959; = p.M379T on NM_001356.5) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- DDX49 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EHD1 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPHB4 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO38 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FRAS1 | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FSCN1 | c.1387A>C p.I463L | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- GDF11 | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGPS1 | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNK5 | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2
- KLHL21 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); called by muse, mutect2
- MACF1 | c.18523G>A p.E6175K (on ENST00000372915; = p.E4220K on NM_012090.5) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- MAMSTR | c.1239T>A p.D413E (on ENST00000318083 / NM_001130915.2; = p.D310E on NM_182574.2) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MAP3K19 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- MAP3K4 | c.3640C>A p.L1214M | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEPCE | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- MIB2 | c.1580A>T p.N527I | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- MLLT3 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MNDA | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.236); called by muse, mutect2
- MSH3 | c.2426_2427insG p.D809Efs*8 | Frame Shift Ins (INS) | VAF 22/161 reads (14%) | called by mutect2, pindel, varscan2
- MUC3A | c.8590A>C p.T2864P | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- NALCN | c.2101A>T p.K701* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- NSRP1 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH11X | c.81C>G p.N27K | Missense Mutation (SNP) | VAF 149/155 reads (96%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PCLO | c.9924G>C p.E3308D | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.361); called by muse, mutect2
- PDE5A | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD2L1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2
- PLEKHH2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.236); called by muse, mutect2
- PNPT1 | c.2332T>G p.S778A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRSS35 | c.925T>G p.F309V | Missense Mutation (SNP) | VAF 107/111 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPN12 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- PTPRQ | c.1936A>G p.I646V (on ENST00000616559; = p.I604V on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, varscan2
- RASA1 | c.938T>C p.L313S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RBBP7 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 123/135 reads (91%) | called by muse, mutect2, varscan2
- RHOB | c.591A>T p.*197Cext*77 | Nonstop Mutation (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- RHOF | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 95/580 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPS6KA4 | c.733A>G p.N245D | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SEC24C | c.3055-4C>G | Splice Region (SNP) | VAF 121/258 reads (47%) | called by muse, mutect2, varscan2
- SERPINB12 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHANK1 | c.4200C>A p.H1400Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHC4 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SKIL | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.134); called by muse, mutect2
- SLC19A1 | c.1147G>C p.A383P | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SP7 | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SUGP1 | c.1713G>T p.M571I | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SUSD4 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 72/236 reads (31%) | called by muse, mutect2, varscan2
- THEMIS | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOMM40L | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- USH2A | c.10144G>T p.V3382F | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- USP29 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ZBED8 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 203/447 reads (45%) | called by muse, mutect2, varscan2
- ZFAT | c.1917G>C p.Q639H | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF211 | c.61_85del p.M21Lfs*5 | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel, varscan2
- ZNF263 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZNF609 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- APOB | c.9588T>C p.F3196= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- C5orf22 | c.645C>T p.C215= | Silent (SNP) | VAF 114/258 reads (44%) | catalogued as rs761401158; called by muse, mutect2, varscan2
- CHST12 | c.876C>T p.F292= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs200096506; called by muse, mutect2, varscan2
- DBH | c.429G>C p.L143= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- ECM2 | c.1830G>A p.L610= | Silent (SNP) | VAF 31/367 reads (8%) | called by muse, mutect2
- EPHX4 | c.223C>A p.R75= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- HSF5 | c.384G>A p.K128= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- IGKV5-2 | c.303G>A p.E101= | Silent (SNP) | VAF 41/46 reads (89%) | catalogued as rs570913016; called by muse, mutect2, varscan2
- KIAA0100 | c.390C>T p.F130= | Silent (SNP) | VAF 41/145 reads (28%) | called by muse, mutect2, varscan2
- LMBR1 | c.495G>A p.V165= | Silent (SNP) | VAF 61/394 reads (15%) | catalogued as rs1267084491; called by muse, mutect2, varscan2
- MAP1A | c.5301A>G p.L1767= | Silent (SNP) | VAF 97/338 reads (29%) | called by muse, mutect2, varscan2
- NIPAL4 | c.414C>G p.L138= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- OR10H1 | c.897G>A p.K299= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as rs1330295058; called by muse, mutect2, varscan2
- PLXNB2 | c.1362C>T p.Y454= | Silent (SNP) | VAF 36/39 reads (92%) | catalogued as rs762597391, COSV63780196; called by muse, mutect2, varscan2
- PPAT | c.1023T>C p.L341= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- PRRC2A | c.828T>A p.P276= | Silent (SNP) | VAF 51/311 reads (16%) | called by muse, mutect2, varscan2
- PTPRQ | c.1851A>T p.I617= (on ENST00000616559; = p.I575= on NM_001145026.2) | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- ROR1 | c.714T>G p.T238= | Silent (SNP) | VAF 106/252 reads (42%) | called by muse, varscan2
- RUFY1 | c.1437G>A p.Q479= | Silent (SNP) | VAF 51/269 reads (19%) | catalogued as rs1419203011; called by muse, mutect2, varscan2
- SEC16B | c.1734C>T p.T578= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as rs764883793; called by muse, mutect2, varscan2
- SLC34A1 | c.1425C>G p.L475= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as CD164714; called by muse, mutect2, varscan2
- TM4SF19 | c.567C>A p.L189= | Silent (SNP) | VAF 39/231 reads (17%) | called by muse, mutect2, varscan2
- TMEM171 | c.972G>A p.P324= | Silent (SNP) | VAF 118/275 reads (43%) | catalogued as rs144105878; called by muse, mutect2, varscan2
- TRAF3 | c.1020C>T p.F340= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1260196286; called by muse, mutect2
- XPA | c.579T>G p.V193= | Silent (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- ZNF225 | c.639C>T p.F213= | Silent (SNP) | VAF 41/223 reads (18%) | called by muse, mutect2, varscan2
- ZNF281 | c.2040T>G p.T680= | Silent (SNP) | VAF 46/431 reads (11%) | called by muse, mutect2, varscan2
- ZNF446 | c.1062C>T p.H354= | Silent (SNP) | VAF 177/367 reads (48%) | catalogued as rs1311455026; called by muse, mutect2, varscan2
- AASDHPPT | chr11:106077660 T>G | 5'Flank (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- ABCA12 | c.164-11414T>G | Intron (SNP) | VAF 132/283 reads (47%) | called by muse, mutect2, varscan2
- ABRA | c.*764C>T | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs1376587045; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-928G>A | Intron (SNP) | VAF 55/298 reads (18%) | called by muse, mutect2, varscan2
- AC139099.3 | n.502G>A | RNA (SNP) | VAF 73/73 reads (100%) | catalogued as rs1304425268; called by muse, mutect2, varscan2
- ADGB | chr6:146598872 C>G | 5'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- ADGB | c.4818+5562G>C | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- AGBL4 | c.*88A>G | 3'UTR (SNP) | VAF 97/521 reads (19%) | catalogued as rs1382813091; called by muse, mutect2, varscan2
- AKT1S1 | c.*363G>C | 3'UTR (SNP) | VAF 124/231 reads (54%) | catalogued as rs1483845774; called by muse, mutect2, varscan2
- AMOTL2 | c.*762A>T | 3'UTR (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- AP000769.5 | chr11:65501039 C>G | 5'Flank (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501040 C>G | 5'Flank (SNP) | VAF 55/110 reads (50%) | catalogued as rs753282151; called by muse, mutect2, varscan2
- AP002414.4 | n.704G>C | RNA (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*1816T>A | 3'UTR (SNP) | VAF 49/52 reads (94%) | catalogued as rs1414312476; called by muse, mutect2, varscan2
- ARHGAP28 | c.*762_*796del | 3'UTR (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel
- ARL14EP | c.-63-46G>T | Intron (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- ARL3 | c.-95C>T | 5'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- ASB9P1 | n.507_538del | RNA (DEL) | VAF 22/231 reads (10%) | called by mutect2, pindel
- BIN2 | c.603-107_603-93del | Intron (DEL) | VAF 60/219 reads (27%) | called by mutect2, pindel, varscan2
- CCDC3 | c.*638A>G | 3'UTR (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- CCDC86 | c.-5G>A | 5'UTR (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- CD2AP | c.*663T>G | 3'UTR (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2
- CD84 | chr1:160546004 del C | 3'Flank (DEL) | VAF 8/62 reads (13%) | catalogued as rs67091022; called by pindel, varscan2
- CDC5L | c.*2775C>G | 3'UTR (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- CHMP7 | c.*385C>A | 3'UTR (SNP) | VAF 53/56 reads (95%) | called by muse, mutect2, varscan2
- CIART | c.-137C>T | 5'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- COL4A4 | c.*756A>G | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by mutect2, varscan2
- CPLANE1 | c.*2899A>C | 3'UTR (SNP) | VAF 60/260 reads (23%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1307C>T | 3'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as rs1306974695; called by muse, mutect2
- CUBN | c.593+801C>G | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- DCX | c.*691G>C | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- DMBX1 | c.*175A>T | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- DMD | c.*772G>T | 3'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- DNAJC16 | chr1:15574995 C>T | 3'Flank (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- E2F6 | c.*1916C>T | 3'UTR (SNP) | VAF 25/120 reads (21%) | catalogued as rs966812923; called by muse, mutect2, varscan2
- EIF4A2 | c.29+211T>G | Intron (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2
- ENOSF1 | c.1251-37C>T | Intron (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- EPB41L5 | c.*460C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- ERMN | c.*1202A>T | 3'UTR (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- ERO1B | c.*1434G>C | 3'UTR (SNP) | VAF 28/140 reads (20%) | catalogued as rs1021412175; called by muse, mutect2, varscan2
- FAM133A | c.*270dup | 3'UTR (INS) | VAF 14/26 reads (54%) | catalogued as rs769947198; called by mutect2, varscan2
- FAM221B | c.743-1538G>T | Intron (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- FKBP15 | c.*3431G>A | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- FLT3LG | chr19:49487415 G>A | 3'Flank (SNP) | VAF 8/47 reads (17%) | catalogued as rs1443239401; called by muse, mutect2
- GNPDA1 | c.-7+293G>A | Intron (SNP) | VAF 48/272 reads (18%) | called by muse, mutect2, varscan2
- GPAM | c.2121+422G>T | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- GPX8 | c.*445G>A | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- HPSE | c.*1569T>C | 3'UTR (SNP) | VAF 8/58 reads (14%) | catalogued as rs1050304857; called by muse, mutect2, varscan2
- IGKV5-2 | c.-38T>C | 5'UTR (SNP) | VAF 62/68 reads (91%) | catalogued as rs773609645; called by muse, mutect2, varscan2
- IRF4 | c.*979G>C | 3'UTR (SNP) | VAF 18/88 reads (20%) | catalogued as COSV66706473; called by muse, mutect2, varscan2
- IZUMO4 | c.370+178C>T | Intron (SNP) | VAF 96/209 reads (46%) | catalogued as rs980222147; called by muse, mutect2, varscan2
- JAM2 | c.821+12T>A | Intron (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- LPP | c.*15035G>T | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- LRRC75A | c.*1020G>A | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- LTB | c.208+70A>T | Intron (SNP) | VAF 66/218 reads (30%) | catalogued as rs555196393; called by muse, mutect2, varscan2
- MAP11 | c.-95C>A | 5'UTR (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- METTL6 | c.673+319G>A | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- MGAT4EP | n.867G>C | RNA (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- MGLL | c.-20-293G>A | Intron (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- MIR3622B | chr8:27701807 T>G | 5'Flank (SNP) | VAF 61/65 reads (94%) | called by muse, mutect2, varscan2
- MTO1 | c.*5922A>G | 3'UTR (SNP) | VAF 28/33 reads (85%) | called by muse, mutect2, varscan2
- MTPN | c.-250G>T | 5'UTR (SNP) | VAF 50/248 reads (20%) | catalogued as rs1001566846, COSV67599722; called by muse, mutect2, varscan2
- NDUFA7 | chr19:8321399 C>A | 5'Flank (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- NHLH2 | c.*1042C>T | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- NIPAL3 | c.1021+359G>A | Intron (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- NME9 | c.-115G>T | 5'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- NOVA1 | c.280+45646A>C | Intron (SNP) | VAF 48/53 reads (91%) | called by muse, mutect2, varscan2
- OR9Q1 | c.*1040T>G | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- PAQR3 | c.*126-2485C>T | Intron (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- PIP4K2B | c.-454dup | 5'UTR (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- PLAUR | c.310+97C>A | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- PLB1 | c.937-348G>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- PRDM5 | c.*173T>G | 3'UTR (SNP) | VAF 23/51 reads (45%) | catalogued as rs1042735473, COSV53356670; called by muse, mutect2, varscan2
- PRKAA1 | chr5:40798281 G>A | 5'Flank (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- PRKCZ | c.334+11834G>A | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+1251G>A | Intron (SNP) | VAF 8/187 reads (4%) | called by muse, mutect2
- RAPGEF2 | c.*390T>C | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by mutect2, varscan2
- RASGRP3 | c.1084-85del | Intron (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- RFX5 | c.*761A>G | 3'UTR (SNP) | VAF 42/184 reads (23%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.*790A>G | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- RICTOR | c.*3159C>T | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- RPS13 | c.152-318C>G | Intron (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863458 G>C | 5'Flank (SNP) | VAF 77/214 reads (36%) | called by muse, mutect2, varscan2
- SIRT6 | c.195-48T>A | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- SLC19A2 | c.-87C>A | 5'UTR (SNP) | VAF 14/505 reads (3%) | catalogued as rs1198972153; called by muse, mutect2
- SLC38A2 | c.*2896A>G | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- SMARCC1 | chr3:47782059 C>A | 5'Flank (SNP) | VAF 144/308 reads (47%) | called by muse, mutect2, varscan2
- SNU13 | chr22:41694301 G>A | 5'Flank (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- SPINDOC | c.935-3578G>A | Intron (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
- STXBP4 | c.*3867C>G | 3'UTR (SNP) | VAF 60/112 reads (54%) | called by muse, mutect2, varscan2
- TMEM230 | c.*226G>T | 3'UTR (SNP) | VAF 55/369 reads (15%) | called by muse, mutect2, varscan2
- TOMM40L | c.685-43C>T | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- TP63 | c.*1392T>G | 3'UTR (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- TRAK2 | c.*821G>A | 3'UTR (SNP) | VAF 4/87 reads (5%) | called by muse, mutect2
- TRAM2 | c.*2182C>T | 3'UTR (SNP) | VAF 15/121 reads (12%) | catalogued as rs77359883; called by muse, mutect2
- TSGA13 | c.659-63T>A | Intron (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- TXNDC2 | c.-199G>A | 5'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- UBE3C | c.1331+2117C>T | Intron (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- UBXN7 | c.*7363A>G | 3'UTR (SNP) | VAF 38/164 reads (23%) | called by muse, mutect2, varscan2
- VGLL3 | c.*2639T>G | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- VPS33B | c.779-29T>A | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- VSX2 | c.*90A>T | 3'UTR (SNP) | VAF 54/62 reads (87%) | called by muse, mutect2, varscan2
- YY1 | c.*1565G>C | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173867758 G>A | 5'Flank (SNP) | VAF 18/233 reads (8%) | called by muse, mutect2
- ZNF189 | c.*247G>A | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ZNF286A | c.*2706del | 3'UTR (DEL) | VAF 19/145 reads (13%) | called by mutect2, pindel, varscan2
- ZNF44 | c.*800C>T | 3'UTR (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- ZNF480 | c.*816+136A>T | Intron (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- ZNF621 | c.-3G>A | 5'UTR (SNP) | VAF 132/320 reads (41%) | catalogued as rs768165637; called by muse, mutect2, varscan2
- ZNF638 | c.3261+159A>C | Intron (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- ZRANB2 | c.*351G>A | 3'UTR (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
